Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A8O2, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A8O2-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Tumor is located in Abdominal Esophagus, nearby of Zlines. It is ulcerated and invasive, with 3.5x3x3cm in size, soft and white-gray surface.

Microscopic Description: Mucosa is ulcerated. Tumor tissue arranges in the form of group or sheets or trabecular of tumor cells. The malignant cells have moderate, light eosinophilic keratinized cytoplasm. The nuclei are enlarged, variability in size and shape, containing coarse clumped chromatin with prominent nucleoli. Mitotic figures are present. Tumor invades in fat tissue. Stroma is fibrous and invasion of lymphocytes.

Diagnosis Details: Squamous cell carcinoma, Grade III, infiltrating adventitia

Comments:

Formatted Path Reports: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Esophagectomy

Tumor site: Abdominal esophagus

Tumor size: 3.5 x 3 x 3 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Adventitia

Lymph nodes: 6/20 positive for metastasis (Regional 6/20)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Not specified

Comments: None

ICD-O-3

Carcinoma, squamous cell NOS
Site: Esophagus, distal
path: Abdominal esophagus
8070/3
C15.5
C15.2
JAD 11/26/13

Source: NCI Genomic Data Commons file bc99052a-d6fc-47e7-8fc5-fdcf1d6a4129 (TCGA-IG-A8O2.54F24B19-60D9-445E-9910-1AE4B2B6CBA3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).